Somatic mutation profile of tumor specimen TCGA-DC-6683-01A (aliquot TCGA-DC-6683-01A-11D-1826-10) from TCGA case TCGA-DC-6683, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.6 years (15,918 days).
Specimen TCGA-DC-6683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f945085-2d00-4eb4-8f0e-986c416432c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6683-10A (Blood Derived Normal), aliquot TCGA-DC-6683-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8f1c3d1-1ccc-48a3-a9d0-aa4962504650

The open-access MAF lists 74 somatic variants for this specimen: 52 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 24/45 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- A2M | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs531579697, COSV59389051; called by mutect2, varscan2
- ACBD6 | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.686); catalogued as COSV62575359; called by muse, mutect2, varscan2
- ARL6IP4 | c.1105C>T p.R369C (on ENST00000315580 / NM_018694.3; = p.R350C on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs756356882, COSV54905848; called by muse, varscan2
- ASB7 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.006); catalogued as COSV100235314; called by muse, mutect2
- COL6A3 | c.6263C>T p.P2088L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113896755; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CPT1B | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141802871; called by muse, mutect2, varscan2
- CPXM1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as rs767256988, COSV66046354; called by muse, mutect2, varscan2
- DHX8 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs777020341, COSV52255555; called by muse, mutect2, varscan2
- DKK3 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV58869722; called by muse, mutect2, varscan2
- DKKL1 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV99678768; called by mutect2, varscan2
- DNAH10 | c.4321G>C p.D1441H (on ENST00000409039; = p.D1380H on NM_207437.3) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV68988319, COSV68998791; called by muse, mutect2, varscan2
- DNPEP | c.590+1G>A p.X197_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56111581; called by muse, mutect2, varscan2
- EFCAB1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50619384; called by muse, mutect2, varscan2
- EFHB | c.1417A>T p.M473L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV55551718; called by muse, mutect2, varscan2
- EIPR1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756185398, COSV66132020; called by muse, mutect2, varscan2
- ERC1 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100706504; called by muse, mutect2, varscan2
- FUBP1 | c.121-1G>T p.X41_splice | Splice Site (SNP) | VAF 22/84 reads (26%) | catalogued as rs181446878, COSV53940935; called by mutect2, varscan2
- GAB4 | c.1657C>A p.Q553K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs1310800106, COSV68755391; called by mutect2, varscan2
- GPR149 | c.1599T>A p.S533R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67669108; called by muse, mutect2, varscan2
- LCE3D | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs371301948, COSV64231079; called by muse, mutect2, varscan2
- LRRC15 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61651051; called by muse, mutect2, varscan2
- LY9 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs146628334; called by muse, mutect2, varscan2
- MAP1A | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs888121977, COSV55811383; called by muse, mutect2, varscan2
- MEP1B | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs201834412, COSV52495894; called by muse, mutect2, varscan2
- MYO5A | c.4136A>G p.N1379S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62563089; called by muse, varscan2
- NAV3 | c.6079A>T p.S2027C (on ENST00000397909 / NM_001024383.2; = p.S2005C on NM_014903.6) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV57101744; called by muse, mutect2, varscan2
- NPTX1 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776036; called by muse, mutect2, varscan2
- NUDCD1 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53459288; called by muse, mutect2, varscan2
- OR13C3 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV101053300, COSV66166122; called by muse, mutect2, varscan2
- OR5B2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.367); catalogued as COSV56909231; called by muse, mutect2, varscan2
- PIWIL1 | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs117506395; called by muse, mutect2, varscan2
- RANBP2 | c.7709G>T p.S2570I | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99312853; called by muse, mutect2, varscan2
- RET | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs765654609, COSV60703525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHAG | c.968G>T p.R323M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV100006348; called by muse, mutect2, varscan2
- RHOJ | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs765688403, COSV57460516; called by muse, mutect2, varscan2
- RYR2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs763802687, COSV63703359; called by muse, mutect2, varscan2
- SACS | c.4160C>A p.P1387H | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV101207577, COSV66543016; called by muse, mutect2
- SALL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1223836455, COSV51758197; called by muse, mutect2, varscan2
- SMG6 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs777689390, COSV53972698; called by muse, mutect2, varscan2
- SPACA7 | c.240A>G p.L80= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99366830; called by muse, mutect2, varscan2
- SPHKAP | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762844015, COSV100763991, COSV60889811; called by muse, mutect2, varscan2
- STK31 | c.675del p.K225Nfs*35 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs746386632, COSV63453772; called by mutect2, varscan2
- STYXL2 | c.3127C>T p.R1043C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs371920799, COSV54803001, COSV99609645; called by muse, mutect2, varscan2
- TCF7L2 | c.1258C>T p.R420W (on ENST00000355995 / NM_001367943.1; = p.R397W on NM_030756.5) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53335898; called by muse, mutect2, varscan2
- TTN | c.11936C>G p.S3979* (on ENST00000591111; = p.S3933* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV60243378; called by muse, mutect2, varscan2
- UNC13C | c.256T>A p.F86I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV52906728; called by muse, mutect2, varscan2
- ZNF587 | c.1431C>G p.H477Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100299614; called by muse, mutect2, varscan2
- ZNF644 | c.2650C>G p.Q884E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100494617; called by muse, mutect2
- APC | c.2563_2564dup p.R856Nfs*6 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, varscan2
- APC | c.4463_4465delinsA p.L1488Yfs*25 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | called by pindel, varscan2*
- ADAMTS1 | c.2544T>C p.S848= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99536391; called by muse, mutect2, varscan2
- ARID2 | c.15G>A p.T5= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57611241; called by muse, mutect2, varscan2
- CEP170B | c.2322C>T p.P774= (on ENST00000453495; = p.P703= on NM_015005.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV69023873; called by mutect2, varscan2
- ECEL1 | c.2322G>T p.V774= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV58813700; called by muse, mutect2, varscan2
- EXOSC8 | c.234C>T p.Y78= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs747216574, COSV53509793; called by muse, mutect2, varscan2
- FOXL2 | c.1095C>T p.S365= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1409535939, COSV100374726; called by muse, mutect2, varscan2
- GANAB | c.9G>A p.A3= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs773629187, COSV57952967; called by muse, mutect2, varscan2
- GPR179 | c.5601G>A p.L1867= (on ENST00000621958; = p.L1866= on NM_001004334.4) | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- IHH | c.564C>T p.C188= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs775145746, COSV99838748; called by muse, varscan2
- KIR2DL3 | c.690A>T p.S230= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100668005; called by muse, mutect2, varscan2
- LZTR1 | c.945C>T p.D315= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs559942119, COSV53148190; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MAGEE1 | c.1633A>C p.R545= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV63911570; called by muse, mutect2, varscan2
- NAP1L3 | c.30G>A p.S10= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59076985; called by muse, mutect2, varscan2
- PCBP4 | c.309C>T p.T103= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs755532537, COSV59055508; called by muse, mutect2, varscan2
- PCDH18 | c.2868G>A p.T956= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1156276110, COSV61266536; called by muse, mutect2, varscan2
- PRKD2 | c.1816C>A p.R606= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52188783; called by muse, mutect2, varscan2
- PSG3 | c.969A>T p.P323= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59506065; called by muse, mutect2, varscan2
- SEPSECS | c.600A>T p.T200= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV57206961; called by muse, mutect2, varscan2
- SRGAP3 | c.2328C>T p.R776= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs138152185, COSV64535899; called by muse, mutect2, varscan2
- TRBV20-1 | c.216C>T p.Y72= | Silent (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- VWA1 | c.723C>T p.G241= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100100773; called by muse, mutect2, varscan2
- ADGRG6 | c.*114G>T | 3'UTR (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51598236; called by muse, mutect2, varscan2
